Somatic mutation profile of tumor specimen TCGA-H7-A6C4-01A (aliquot TCGA-H7-A6C4-01A-11D-A30E-08) from TCGA case TCGA-H7-A6C4, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 36.0 years (13,137 days).
Specimen TCGA-H7-A6C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5637cc6b-0a5c-4bc1-8a7e-94aaf2145db5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H7-A6C4-10A (Blood Derived Normal), aliquot TCGA-H7-A6C4-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0e9e9b9-a1d4-4d82-b664-9dc428c2b71c

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANO8 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368368418; called by muse, mutect2, varscan2
- ARHGAP27 | c.1937C>T p.A646V (on ENST00000428638 / NM_001282290.1; = p.A305V on NM_199282.3) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs773861287, COSV65357438; called by muse, mutect2, varscan2
- ARHGAP31 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1400666120, COSV51795175; called by muse, mutect2
- ASAP2 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750088370, COSV99855636; called by muse, mutect2, varscan2
- BRINP1 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1245745301, COSV56292056; called by muse, mutect2, varscan2
- CRISP3 | c.691G>A p.D231N (on ENST00000371159 / NM_001368123.1; = p.D213N on NM_006061.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs996891773, COSV53819037; called by muse, mutect2, varscan2
- DNAH9 | c.4321C>A p.Q1441K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1253290057, COSV99303426; called by mutect2, varscan2
- DPYD | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs143154602, CM145337; called by muse, mutect2, varscan2
- FOS | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100338389; called by muse, mutect2
- GATA3 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1266983268, COSV60516000; called by muse, mutect2, varscan2
- GHR | c.799T>C p.W267R | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100049668; called by muse, mutect2
- GRXCR1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs778774192, COSV67670223; called by muse, mutect2, varscan2
- JMJD1C | c.2758C>T p.L920F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100550075; called by muse, mutect2, varscan2
- LINGO2 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100430056; called by muse, mutect2, varscan2
- MAGI3 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV56845838; called by muse, mutect2
- NUMA1 | c.3616G>C p.E1206Q | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100705719; called by muse, mutect2
- ORC2 | c.932T>G p.I311S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99309333; called by muse, mutect2, varscan2
- PPFIA2 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV100331348; called by muse, mutect2, varscan2
- STK32B | c.827A>G p.D276G | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV99283876; called by muse, mutect2, varscan2
- SYCE1 | c.778C>T p.R260C (on ENST00000343131 / NM_001143764.3; = p.R224C on NM_130784.3) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs143005509; called by muse, mutect2, varscan2
- USP28 | c.1743G>A p.Q581= | Splice Region (SNP) | VAF 3/31 reads (10%) | catalogued as COSV50163927, COSV99134411; called by muse, mutect2
- WBP11 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.98); catalogued as rs368417102; called by muse, mutect2, varscan2
- WDR33 | c.2581C>A p.Q861K | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100459468; called by muse, mutect2, varscan2
- XPO1 | c.2235T>G p.I745M | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762581181, COSV101294137; called by muse, mutect2, varscan2
- ZNF25 | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100224470; called by muse, mutect2
- FAT2 | c.11736_11737dup p.L3913Pfs*12 | Frame Shift Ins (INS) | VAF 28/136 reads (21%) | called by mutect2, pindel, varscan2
- MYH9 | c.1905_1919delinsGGT p.F636_K640delinsV | In Frame Del (DEL) | VAF 15/57 reads (26%) | called by pindel, varscan2*
- CRIM1 | c.936C>T p.V312= | Silent (SNP) | VAF 52/260 reads (20%) | catalogued as rs868499327, COSV99752173; called by muse, mutect2, varscan2
- CROCC | c.5433G>A p.Q1811= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100977583; called by muse, mutect2, varscan2
- FGFR1OP2 | c.588G>A p.Q196= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99986801; called by muse, mutect2
- HOXB2 | c.177C>T p.G59= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as rs1474342416, COSV100344433; called by muse, varscan2
- LHFPL5 | c.78C>T p.G26= | Silent (SNP) | VAF 46/227 reads (20%) | catalogued as COSV64177696; called by muse, mutect2, varscan2
- PRDM9 | c.84C>T p.F28= | Silent (SNP) | VAF 38/226 reads (17%) | catalogued as COSV99689666; called by muse, mutect2, varscan2
- TMEM63B | c.2238G>A p.T746= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as rs778067413, COSV99440903; called by muse, mutect2, varscan2
- DOT1L | c.4606+1214G>A | Intron (SNP) | VAF 12/176 reads (7%) | catalogued as rs758539997; called by muse, mutect2
